FM case AD5981 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/01c65274-5bee-4774-83c0-8f1adfe0c30e

Male, 54.4 years: diagnosis not reported by GDC of the lung; specimen biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Tumor.
